Somatic mutation profile of tumor specimen 0DSPLW from CCDI case PBCIBZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.5 years (1,277 days).
Specimen 0DSPLW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018b216e-2aa5-4eff-811b-efbb45065851.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSPM0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a40dbefe-cf6f-4448-99b2-1b5785847d3b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK11A | c.586C>G p.R196G (on ENST00000378633 / NM_001313896.2; = p.R206G on NM_024011.4) | Missense Mutation (SNP) | VAF 234/1377 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1161756757; called by muse, mutect2, varscan2
- UST | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 136/682 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163124812, COSV100819918; called by muse, varscan2
- ZC3H10 | c.324A>G p.T108= | Silent (SNP) | VAF 37/590 reads (6%) | called by muse, mutect2
